Somatic mutation profile of tumor specimen MMRF_2119_1_BM_CD138pos (aliquot MMRF_2119_1_BM_CD138pos_T1_KHS5U_L08638) from MMRF case MMRF_2119, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.0 years (22,268 days).
Specimen MMRF_2119_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 525ffa1e-6071-4c9a-bf45-7f3534865606.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2119_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2119_1_PB_Whole_C2_KHS5U_L08637; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/72a8c1de-321a-441a-bf78-9b281ef0c5e2

The open-access MAF lists 120 somatic variants for this specimen: 46 protein-altering or splice-affecting, 12 silent, 62 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, 3'UTR 40, Silent 12, Intron 9, 5'UTR 7, 3'Flank 3, 5'Flank 3, Frame Shift Del 2, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 70/150 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ARHGEF10 | c.772G>A p.D258N (on ENST00000398564; = p.D233N on NM_014629.4) | Missense Mutation (SNP) | VAF 56/100 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1302587817; called by muse, mutect2, varscan2
- ATG13 | c.167A>G p.K56R | Missense Mutation (SNP) | VAF 79/193 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.937); catalogued as rs766243483; called by muse, mutect2, varscan2
- DENND1B | c.2171C>T p.S724L | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.236); catalogued as rs1213502120, COSV54147668; called by muse, mutect2, varscan2
- DIAPH1 | c.1223C>T p.P408L | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.583); catalogued as rs1347749897; called by muse, mutect2, varscan2
- IGHV2-70 | c.248C>G p.S83C | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs561745237; called by muse, varscan2
- IGHV2-70 | c.244A>C p.T82P | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375530938; called by muse, varscan2
- IGHV2-70 | c.240C>A p.Y80* | Nonsense Mutation (SNP) | VAF 26/46 reads (57%) | catalogued as rs111365811; called by muse, varscan2
- IGLV4-60 | c.226A>G p.S76G | Missense Mutation (SNP) | VAF 56/62 reads (90%) | SIFT tolerated (0.15); PolyPhen benign (0.143); catalogued as rs567826954; called by muse, mutect2, varscan2
- OR2AK2 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 55/149 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.095); catalogued as rs372430446; called by muse, mutect2, varscan2
- PRPH2 | c.434A>G p.D145G | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as CD075520; called by muse, mutect2, varscan2
- SCD5 | c.718A>G p.S240G | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761817397; called by muse, mutect2, varscan2
- SEMA6A | c.2404G>A p.D802N | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.682); catalogued as rs764076664; called by muse, mutect2, varscan2
- SPHKAP | c.3880C>T p.R1294W | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs750750848; called by muse, mutect2, varscan2
- TBX20 | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV68786136; called by muse, mutect2, varscan2
- TENM2 | c.2305G>A p.V769M (on ENST00000518659 / NM_001122679.2; = p.V537M on NM_001080428.3) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.473); catalogued as rs368507082, COSV69134332; called by muse, mutect2, varscan2
- TOX2 | c.14G>A p.R5H | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.057); catalogued as rs1200526715, COSV57883754; called by muse, mutect2, varscan2
- USP54 | c.3367C>T p.P1123S | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.261); catalogued as rs772918929; called by muse, mutect2, varscan2
- ARMC2 | c.1318T>G p.F440V | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP8A1 | c.896del p.L299* | Frame Shift Del (DEL) | VAF 7/59 reads (12%) | called by mutect2, pindel, varscan2
- CARMIL1 | c.2543G>C p.R848T | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CHRDL2 | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- DIAPH2 | c.1764G>A p.M588I | Missense Mutation (SNP) | VAF 42/42 reads (100%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAJC13 | c.3649G>T p.A1217S | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.037); called by muse, mutect2
- ENPP5 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.009); called by muse, mutect2
- GTF3C2 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- HK1 | c.209C>T p.S70F | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- HNRNPH3 | c.929G>C p.G310A | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.992); called by muse, mutect2
- IFFO2 | c.1298A>G p.E433G | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- IGHG1 | c.314_324del p.K105Mfs*8 | Frame Shift Del (DEL) | VAF 33/38 reads (87%) | called by mutect2, pindel, varscan2
- IGLV1-47 | c.13C>A p.P5T | Missense Mutation (SNP) | VAF 35/36 reads (97%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.361); called by muse, varscan2
- IL1RAP | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- ITPKB | c.1852G>T p.D618Y | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LAMA4 | c.3631G>A p.D1211N (on ENST00000230538 / NM_001105206.3; = p.D1204N on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRN3 | c.1242C>A p.D414E | Missense Mutation (SNP) | VAF 25/219 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LTN1 | c.938G>A p.C313Y | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- MAF | c.212C>A p.P71H | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MRPS7 | c.93G>T p.Q31H | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- MTARC2 | c.568A>G p.T190A | Missense Mutation (SNP) | VAF 60/104 reads (58%) | SIFT tolerated (0.41); PolyPhen benign (0.01); called by muse, mutect2
- NCAM2 | c.1148C>T p.A383V | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- PTPRD | c.1241A>G p.E414G | Missense Mutation (SNP) | VAF 58/229 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ROR1 | c.1028A>C p.H343P | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- SAE1 | c.596T>C p.L199P | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SKIL | c.743C>A p.A248D | Missense Mutation (SNP) | VAF 78/150 reads (52%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- SLC18A3 | c.1158_1170dup p.C391Tfs*63 | Frame Shift Ins (INS) | VAF 21/80 reads (26%) | called by mutect2, varscan2
- ZNF236 | c.3144G>A p.M1048I | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.43); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- C2CD4D | c.804C>T p.V268= | Silent (SNP) | VAF 98/148 reads (66%) | called by muse, varscan2
- CLEC4A | c.423G>A p.L141= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as rs201730459; called by muse, mutect2, varscan2
- COL27A1 | c.3873A>T p.G1291= | Silent (SNP) | VAF 31/41 reads (76%) | called by muse, mutect2, varscan2
- DMXL1 | c.402C>G p.L134= | Silent (SNP) | VAF 45/65 reads (69%) | catalogued as rs773583019; called by muse, mutect2, varscan2
- FAM120B | c.2172G>A p.L724= | Silent (SNP) | VAF 7/12 reads (58%) | called by muse, varscan2
- FAM83D | c.1621C>A p.R541= | Silent (SNP) | VAF 39/100 reads (39%) | called by muse, mutect2, varscan2
- FGD1 | c.804G>A p.L268= | Silent (SNP) | VAF 29/32 reads (91%) | called by muse, mutect2, varscan2
- GIMAP8 | c.1701G>A p.K567= | Silent (SNP) | VAF 17/89 reads (19%) | called by muse, mutect2, varscan2
- HPR | c.753C>T p.C251= | Silent (SNP) | VAF 29/79 reads (37%) | called by muse, varscan2
- OTUB2 | c.273G>A p.E91= | Silent (SNP) | VAF 23/42 reads (55%) | called by muse, mutect2, varscan2
- TRPV6 | c.412C>T p.L138= | Silent (SNP) | VAF 8/151 reads (5%) | called by muse, mutect2
- UGT1A3 | c.645C>T p.L215= | Silent (SNP) | VAF 42/104 reads (40%) | catalogued as rs769797666; called by muse, mutect2, varscan2
- ABCC12 | c.-18C>T | 5'UTR (SNP) | VAF 14/119 reads (12%) | called by muse, mutect2, varscan2
- ADM | c.-152A>G | 5'UTR (SNP) | VAF 16/44 reads (36%) | catalogued as rs1355187061; called by muse, mutect2, varscan2
- AK1 | chr9:127866841 C>T | 3'Flank (SNP) | VAF 68/100 reads (68%) | called by muse, mutect2
- AKT2 | c.*2337A>G | 3'UTR (SNP) | VAF 26/96 reads (27%) | called by muse, mutect2, varscan2
- ANKRD52 | c.*675G>C | 3'UTR (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- ANP32A | c.625-37G>C | Intron (SNP) | VAF 22/76 reads (29%) | called by muse, mutect2, varscan2
- ARL17B | c.*79C>T | 3'UTR (SNP) | VAF 65/315 reads (21%) | called by muse, mutect2, varscan2
- BAIAP2 | chr17:81031273 C>T | 5'Flank (SNP) | VAF 7/66 reads (11%) | called by muse, mutect2
- C1QTNF9 | c.*473A>C | 3'UTR (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2
- CALM1 | c.4-1066_4-1064del | Intron (DEL) | VAF 77/162 reads (48%) | called by pindel, varscan2
- CEP78 | c.*5708C>T | 3'UTR (SNP) | VAF 12/69 reads (17%) | called by muse, mutect2, varscan2
- COX14 | c.*31G>A | 3'UTR (SNP) | VAF 17/31 reads (55%) | catalogued as rs764794729; called by muse, mutect2, varscan2
- CREB3L2 | c.*534C>G | 3'UTR (SNP) | VAF 12/60 reads (20%) | called by muse, mutect2, varscan2
- DENND11 | c.*5282A>T | 3'UTR (SNP) | VAF 19/60 reads (32%) | called by muse, mutect2, varscan2
- ERGIC3 | c.367+38C>T | Intron (SNP) | VAF 33/61 reads (54%) | called by muse, mutect2, varscan2
- ETFBKMT | c.*2279del | 3'UTR (DEL) | VAF 5/55 reads (9%) | called by mutect2, pindel
- FAT3 | c.*305G>C | 3'UTR (SNP) | VAF 28/37 reads (76%) | called by muse, mutect2, varscan2
- GADD45B | c.45-10C>G | Intron (SNP) | VAF 11/62 reads (18%) | called by muse, mutect2, varscan2
- GLYR1 | c.*1058T>C | 3'UTR (SNP) | VAF 12/25 reads (48%) | called by muse, mutect2, varscan2
- GPRC5B | c.*146G>A | 3'UTR (SNP) | VAF 3/50 reads (6%) | catalogued as rs887159415, COSV100245172; called by muse, mutect2
- HGSNAT | c.*1845C>T | 3'UTR (SNP) | VAF 29/79 reads (37%) | called by muse, mutect2, varscan2
- HS3ST1 | c.*4880T>G | 3'UTR (SNP) | VAF 39/92 reads (42%) | called by muse, mutect2, varscan2
- HSP90AA1 | c.*621C>T | 3'UTR (SNP) | VAF 73/154 reads (47%) | called by muse, mutect2, varscan2
- IDH2 | c.-47G>A | 5'UTR (SNP) | VAF 11/29 reads (38%) | called by muse, mutect2, varscan2
- IGLV1-47 | c.-43T>C | 5'UTR (SNP) | VAF 22/23 reads (96%) | called by muse, varscan2
- IGLV4-69 | chr22:22031472 ins TTT | 3'Flank (INS) | VAF 32/36 reads (89%) | called by pindel, varscan2
- INHBA | c.*1522G>A | 3'UTR (SNP) | VAF 13/47 reads (28%) | catalogued as rs915371343; called by muse, mutect2, varscan2
- KIAA0319 | c.*847G>A | 3'UTR (SNP) | VAF 20/45 reads (44%) | called by muse, mutect2, varscan2
- LAMC3 | c.*1859G>A | 3'UTR (SNP) | VAF 6/107 reads (6%) | called by muse, mutect2
- MFSD2A | c.-31A>C | 5'UTR (SNP) | VAF 20/54 reads (37%) | called by muse, mutect2, varscan2
- MFSD8 | c.*2584_*2589del | 3'UTR (DEL) | VAF 47/81 reads (58%) | called by mutect2, pindel, varscan2
- MIR5195 | chr14:106851161 C>T | 5'Flank (SNP) | VAF 46/118 reads (39%) | catalogued as rs777755236; called by muse, varscan2
- MTDH | c.*4167C>A | 3'UTR (SNP) | VAF 29/57 reads (51%) | called by muse, mutect2, varscan2
- MTERF4 | c.*1227G>A | 3'UTR (SNP) | VAF 44/100 reads (44%) | called by muse, mutect2, varscan2
- N4BP2 | c.*679T>G | 3'UTR (SNP) | VAF 26/44 reads (59%) | called by muse, mutect2, varscan2
- NFIA | c.*5102T>C | 3'UTR (SNP) | VAF 34/73 reads (47%) | called by muse, mutect2, varscan2
- NHSL2 | chrX:72132122 C>G | 5'Flank (SNP) | VAF 28/28 reads (100%) | called by muse, mutect2, varscan2
- NLGN1 | c.*1366C>T | 3'UTR (SNP) | VAF 38/74 reads (51%) | called by muse, mutect2, varscan2
- OR51E1 | c.*1431G>T | 3'UTR (SNP) | VAF 28/61 reads (46%) | catalogued as rs924482596; called by muse, mutect2, varscan2
- PBXIP1 | chr1:154944078 C>T | 3'Flank (SNP) | VAF 30/48 reads (63%) | called by muse, mutect2, varscan2
- PCDH12 | c.*441G>A | 3'UTR (SNP) | VAF 12/124 reads (10%) | called by muse, mutect2
- PCNA | c.-148C>T | 5'UTR (SNP) | VAF 92/209 reads (44%) | called by muse, mutect2, varscan2
- PDCD6IP | c.*1337T>G | 3'UTR (SNP) | VAF 5/55 reads (9%) | called by muse, mutect2
- PELI3 | c.*383_*386del | 3'UTR (DEL) | VAF 28/53 reads (53%) | called by mutect2, pindel, varscan2
- PHF12 | c.*40A>G | 3'UTR (SNP) | VAF 40/84 reads (48%) | catalogued as rs1349547571; called by muse, mutect2, varscan2
- PLBD2 | c.*210C>T | 3'UTR (SNP) | VAF 64/128 reads (50%) | catalogued as rs1321614686, COSV55105994; called by muse, mutect2, varscan2
- RALGPS2 | c.*1988T>A | 3'UTR (SNP) | VAF 25/53 reads (47%) | called by muse, mutect2, varscan2
- RARB | c.179-32535T>C | Intron (SNP) | VAF 52/123 reads (42%) | called by muse, mutect2, varscan2
- RGMA | c.*3G>A | 3'UTR (SNP) | VAF 9/39 reads (23%) | catalogued as rs372965441; called by muse, mutect2
- RGS4 | c.378+33G>A | Intron (SNP) | VAF 9/19 reads (47%) | catalogued as rs763819180; called by muse, mutect2, varscan2
- SIRPB2 | c.*47G>A | 3'UTR (SNP) | VAF 20/51 reads (39%) | catalogued as rs1473908870, COSV100708642; called by muse, mutect2, varscan2
- SIRT2 | c.692-53C>T | Intron (SNP) | VAF 9/60 reads (15%) | catalogued as rs1555733969; called by muse, mutect2, varscan2
- SLC16A7 | c.*1892T>G | 3'UTR (SNP) | VAF 25/53 reads (47%) | called by muse, mutect2, varscan2
- SORD | c.*724C>T | 3'UTR (SNP) | VAF 72/262 reads (27%) | called by muse, mutect2, varscan2
- SPATA6L | c.430-1084A>T | Intron (SNP) | VAF 26/94 reads (28%) | called by muse, mutect2, varscan2
- SRD5A2 | c.*75C>T | 3'UTR (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2
- TAT | c.*1009C>T | 3'UTR (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2, varscan2
- TMPRSS3 | c.-61C>T | 5'UTR (SNP) | VAF 20/50 reads (40%) | catalogued as rs749010685; called by muse, mutect2, varscan2
- TRAF3 | c.*2064T>C | 3'UTR (SNP) | VAF 48/108 reads (44%) | catalogued as rs1265652347; called by muse, mutect2, varscan2
- TSPAN9 | c.*243G>A | 3'UTR (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- VGLL3 | c.937+6628C>T | Intron (SNP) | VAF 32/74 reads (43%) | called by muse, mutect2, varscan2
- ZFP37 | c.*4129T>A | 3'UTR (SNP) | VAF 12/39 reads (31%) | called by muse, mutect2, varscan2
